Gene-level copy-number profile of specimen HCM-SANG-0298-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0298-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0298-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 785273de-35d4-4983-9344-466f72a1d4e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0298-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/333b33b4-1f11-4d16-9bc3-fbf77b58f2de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,563; copy number 2: 25,880; copy number 3: 21,443; copy number 4: 6,155; copy number 5: 1,758; copy number 6: 1,032; copy number 7: 1,051; copy number 8: 16; copy number 10: 5.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:137,381,037–137,847,092, 3 genes: DGKI, AC090498.1, AC009245.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,862 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–95,053,992, 1,626 genes, copy number 5 (broad region; genes not listed).
- chr7:88,205,115–89,338,528, 15 genes, copy number 8: SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47.
- chr7:92,487,020–100,928,540, 229 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:120,380,761–120,542,133, 2 genes, copy number 5 (within-gene range 4–5): MRPL13, MTBP.
- chr10:78,696,062–80,778,088, 66 genes, copy number 5–7 (broad region; genes not listed).
- chr10:133,657,235–133,778,699, 17 genes, copy number 5: CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.
- chr13:70,564,267–114,337,626, 512 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–16,053,197, 286 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 6 (within-gene range 4–6): MACROD2-AS1.
- chr20:15,552,157–26,251,546, 239 genes, copy number 5–6 (broad region; genes not listed).
- chr20:30,278,906–64,327,972, 869 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,051. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
